Somatic mutation profile of tumor specimen MMRF_1655_1_BM_CD138pos (aliquot MMRF_1655_1_BM_CD138pos_T1_KBS5U_L05362) from MMRF case MMRF_1655, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.4 years (23,145 days).
Specimen MMRF_1655_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 403df3f9-34c7-4575-8898-881dcd640e6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1655_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1655_1_PB_CD3pos_C2_KBS5U_L05372; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25ff76ef-0874-416c-99d3-a61cb15fdffd

The open-access MAF lists 18 somatic variants for this specimen: 7 protein-altering or splice-affecting, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 5, Missense Mutation 3, Nonsense Mutation 3, Intron 2, 5'Flank 1, Splice Region 1, 5'UTR 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS2 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV52364352, COSV99282325; called by muse, mutect2
- ATXN1L | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 5/72 reads (7%) | catalogued as COSV70235460; called by muse, mutect2
- KCNA6 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as COSV54976729; called by muse, mutect2, varscan2
- LCA5L | c.940C>T p.Q314* | Nonsense Mutation (SNP) | VAF 22/39 reads (56%) | catalogued as COSV99903616; called by muse, mutect2, varscan2
- NPAS1 | c.695G>C p.S232T | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- VDAC1 | c.552-6T>G | Splice Region (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- ZNF138 | c.100T>A p.L34I | Missense Mutation (SNP) | VAF 11/275 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- AL357562.1 | n.179C>T | RNA (SNP) | VAF 16/37 reads (43%) | catalogued as rs778917545; called by muse, mutect2, varscan2
- ALDH4A1 | chr1:18902692 del A | 5'Flank (DEL) | VAF 42/90 reads (47%) | called by mutect2, varscan2
- CFLAR | c.*25G>A | 3'UTR (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- COL5A1 | c.3367-204C>T | Intron (SNP) | VAF 3/18 reads (17%) | catalogued as rs1469128192; called by muse, mutect2
- FREM1 | c.-118T>C | 5'UTR (SNP) | VAF 12/42 reads (29%) | catalogued as COSV66527891; called by mutect2, varscan2
- MRPL40 | c.53+156C>T | Intron (SNP) | VAF 20/31 reads (65%) | called by muse, mutect2, varscan2
- PTGFR | c.*305T>A | 3'UTR (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- RUNDC3B | c.*597C>T | 3'UTR (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- YEATS2 | c.*2021A>G | 3'UTR (SNP) | VAF 10/39 reads (26%) | catalogued as rs956120112; called by muse, mutect2, varscan2
- YY1 | c.*678_*681del | 3'UTR (DEL) | VAF 11/22 reads (50%) | catalogued as rs1365813463; called by mutect2, pindel, varscan2
- ZNF566 | chr19:36445542 G>A | 3'Flank (SNP) | VAF 9/30 reads (30%) | catalogued as rs927955514; called by muse, mutect2, varscan2
